CCDI case PBBTTN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/91e7c7f7-cfe2-4d59-b471-db998d14558d

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.9 years (1,793 days).

Biospecimens (2 samples)
- Sample 0DGUS9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGUTA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
